Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8EL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8EL-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

"Biopsy of cervix":

. Poorly differentiated invasive squamous cell carcinoma

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS
C53.9
JW 11/21/13

Source: NCI Genomic Data Commons file 82b06671-9785-41dc-8187-a8e537db8d54 (TCGA-VS-A8EL.14765542-0003-41A9-8863-BDC90E87594D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).